CCDI case PBCNAX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/9acf63da-6aab-41af-ae0f-f74725d2ae41

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 16.0 years (5,840 days).

Biospecimens (3 samples)
- Samples 0DVM0P, 0DVM1K (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVM1W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
